Somatic mutation profile of tumor specimen 0DUQYT from CCDI case PBCLFZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.3 years (6,301 days).
Specimen 0DUQYT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 407c7e04-e632-4afc-acb5-8f9e2446a347.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUR01 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06a410b3-d1d6-4aae-94f6-e4acdd8d90a5

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'UTR 2, RNA 2, 3'UTR 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 310/1299 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CARD11 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs387907352, CM1211119, COSV62717009, COSV62720895; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GSR | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 42/1742 reads (2%) | SIFT tolerated (0.19); PolyPhen benign (0.431); catalogued as rs1369401364; called by muse, mutect2
- TASOR2 | c.4379A>G p.H1460R | Missense Mutation (SNP) | VAF 62/974 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs188788967; called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 52/1924 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- RAB33B | c.590A>T p.H197L | Missense Mutation (SNP) | VAF 42/1232 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.125); called by muse, mutect2
- REXO5 | c.2196C>G p.S732R | Missense Mutation (SNP) | VAF 44/1189 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- ILF3 | c.1269G>A p.Q423= | Silent (SNP) | VAF 194/763 reads (25%) | catalogued as rs35968299, COSV51558129; called by muse, mutect2, varscan2
- DAPP1 | c.*97G>T | 3'UTR (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 23/380 reads (6%) | called by muse, mutect2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 23/349 reads (7%) | catalogued as rs768118261; called by muse, mutect2
- MMS22L | c.828+43A>G | Intron (SNP) | VAF 44/524 reads (8%) | called by muse, mutect2
- SKIDA1 | c.-60G>A | 5'UTR (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- SKIDA1 | c.-61T>C | 5'UTR (SNP) | VAF 12/344 reads (3%) | catalogued as rs1015442172; called by muse, mutect2
